Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4706, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4706-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, LEFT, RADICAL NEPHRECTOMY –

- A. RENAL CELL CARCINOMA WITH FOCAL SARCOMATOID FEATURES (SEE COMMENT).
- B. FUHRMAN NUCLEAR GRADE IS IV/IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 7.0 CM.
- D. THE TUMOR INVADES THE ADRENAL GLAND.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. NO DEFINITE EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- I. THE UROTHELIUM SHOW
- J. TNM HISTOLOGIC STAGE: pT3a Nx Mx.

COMMENT:

The tumor show predominantly of conventional (clear cell) type with focal area showing a papillary growth pattern. The tumor is present in the adrenal gland, which is highlighted by cytokeratin stain (positive for Cam5.2).

Source: NCI Genomic Data Commons file d77ec9ff-6413-460f-8279-9af597e7370c (TCGA-B0-4706.9E87FE25-1A78-446C-A6DD-156F5739D6CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).